Somatic mutation profile of tumor specimen TCGA-AP-A054-01A (aliquot TCGA-AP-A054-01A-11W-A062-09) from TCGA case TCGA-AP-A054, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 64.1 years (23,404 days).
Specimen TCGA-AP-A054-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57535093-a4ef-4dbc-8faa-9eefca754773.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A054-10A (Blood Derived Normal), aliquot TCGA-AP-A054-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83a6ed08-28fe-451b-ae03-ca8caf21fa57

The open-access MAF lists 1,396 somatic variants for this specimen: 1,069 protein-altering or splice-affecting, 296 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 805, Silent 296, Frame Shift Del 143, Frame Shift Ins 46, Splice Site 33, Nonsense Mutation 25, Intron 13, Splice Region 10, 3'Flank 6, RNA 5, 3'UTR 3, In Frame Del 3.

Variants (750 of 1,396; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG2 | c.1545del p.F515Lfs*17 (on ENST00000379869 / NM_001079858.3; = p.F512Lfs*17 on NM_005756.4) | Frame Shift Del (DEL) | VAF 33/93 reads (35%) | catalogued as rs774488954; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BBS10 | c.235dup p.T79Nfs*17 | Frame Shift Ins (INS) | VAF 48/128 reads (38%) | catalogued as rs760693838; ClinVar: pathogenic; called by mutect2, varscan2
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, varscan2
- FOXP2 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 70/169 reads (41%) | catalogued as rs121908378, CM051480, COSV100647565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 46/73 reads (63%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MMAA | c.455del p.P152Lfs*9 | Frame Shift Del (DEL) | VAF 43/135 reads (32%) | catalogued as rs1553958127; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 131/307 reads (43%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 79/165 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 128/274 reads (47%) | hotspot (GDC flag); catalogued as COSV64294647, COSV64306028; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 106/252 reads (42%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.371_372del p.I124Rfs*6 | Frame Shift Del (DEL) | VAF 49/134 reads (37%) | catalogued as rs1566186125; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780068, CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 55/179 reads (31%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.3992T>A p.V1331E | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55289098; called by muse, mutect2, varscan2
- AADACL2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 179/410 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.08); catalogued as COSV62930035, COSV99070636; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCC2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.118); catalogued as COSV100965672; called by muse, mutect2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs749943218; called by mutect2, varscan2
- ABO | c.937A>T p.K313* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV101506017; called by muse, mutect2, varscan2
- ACACB | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58132159; called by muse, mutect2, varscan2
- ACACB | c.5326A>G p.R1776G | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58132167; called by muse, varscan2
- ACTB | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV59316637; called by muse, mutect2, varscan2
- ACTG1 | c.379T>G p.F127V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV59510098; called by muse, mutect2, varscan2
- ADAMTS1 | c.2431A>T p.I811F | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV53169742; called by muse, mutect2, varscan2
- ADAMTS10 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV54353693; called by muse, mutect2, varscan2
- ADAMTS19 | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV50741519; called by muse, mutect2, varscan2
- ADAMTS19 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as COSV50741549; called by muse, mutect2, varscan2
- ADCK2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as rs1237618441, COSV50780776; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 62/156 reads (40%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRV1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV67983194; called by muse, mutect2, varscan2
- ADGRV1 | c.7420G>A p.V2474I | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV67983197; called by muse, mutect2, varscan2
- ADHFE1 | c.98-2A>C p.X33_splice | Splice Site (SNP) | VAF 50/164 reads (30%) | catalogued as COSV52554509; called by muse, mutect2, varscan2
- AGO4 | c.2303A>G p.Q768R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV64616881; called by muse, mutect2, varscan2
- AHDC1 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV55938023; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 85/190 reads (45%) | catalogued as rs778351035; called by pindel, varscan2
- AK9 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58141053; called by muse, varscan2
- AKAP8 | c.1395A>G p.K465= | Splice Region (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54102062; called by muse, mutect2, varscan2
- ALCAM | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as rs774445203, COSV60247106; called by muse, mutect2, varscan2
- ALG10 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56792203; called by muse, mutect2, varscan2
- ALG9 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV67644127; called by muse, mutect2, varscan2
- ALYREF | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1388519159, COSV100485918; called by muse, mutect2
- AMBRA1 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV54052275; called by muse, mutect2, varscan2
- AMOTL1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as COSV54415059; called by muse, mutect2, varscan2
- ANK1 | c.4720A>G p.T1574A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as rs143760629; called by muse, mutect2, varscan2
- ANKAR | c.2878-2A>G p.X960_splice | Splice Site (SNP) | VAF 10/100 reads (10%) | catalogued as COSV99854840; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7258A>G p.M2420V | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51844857; called by muse, mutect2, varscan2
- ANKRD11 | c.5630del p.P1877Rfs*86 | Frame Shift Del (DEL) | VAF 31/90 reads (34%) | catalogued as COSV56357612; called by mutect2, pindel, varscan2
- ANKRD17 | c.4900A>G p.K1634E | Missense Mutation (SNP) | VAF 127/335 reads (38%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.006); catalogued as COSV58218608; called by muse, mutect2, varscan2
- ANKRD24 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 115/241 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV53669501; called by muse, mutect2, varscan2
- ANKRD35 | c.508T>C p.S170P | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62910087; called by muse, mutect2, varscan2
- ANO8 | c.2821A>G p.T941A | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV50175300; called by muse, mutect2, varscan2
- ANXA3 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53714143; called by muse, mutect2, varscan2
- AP2A1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1407640650, COSV62818050; called by muse, mutect2, varscan2
- AP3D1 | c.3049C>A p.L1017I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100643130; called by muse, mutect2
- APAF1 | c.2304+2T>C p.X768_splice (on ENST00000551964 / NM_181861.2; = p.X757_splice on NM_001160.3) | Splice Site (SNP) | VAF 67/193 reads (35%) | catalogued as COSV59663290; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 82/194 reads (42%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARHGAP22 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50938126; called by muse, mutect2, varscan2
- ARHGEF11 | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV63811648; called by muse, mutect2, varscan2
- ARHGEF6 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51689477, COSV51696118; called by muse, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 25/162 reads (15%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARID4B | c.666T>C p.F222= | Splice Region (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99936601; called by muse, mutect2, varscan2
- ARID5B | c.948G>C p.E316D | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV54418267; called by muse, mutect2, varscan2
- ARID5B | c.3346A>G p.M1116V | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV54418275; called by muse, mutect2, varscan2
- ARIH1 | c.1660T>C p.Y554H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV65911308; called by muse, mutect2, varscan2
- ARL2BP | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54655968; called by muse, mutect2, varscan2
- ASAP3 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV60874142; called by muse, mutect2, varscan2
- ATAD2B | c.3393A>G p.A1131= | Splice Region (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99478752; called by muse, mutect2, varscan2
- ATF6B | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV64351609, COSV64351636; called by muse, mutect2, varscan2
- ATP13A3 | c.1137A>G p.I379M | Missense Mutation (SNP) | VAF 123/307 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV55463415; called by muse, mutect2, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATP1A4 | c.1648T>G p.L550V | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV63626136; called by muse, mutect2, varscan2
- ATP1A4 | c.2035A>G p.I679V | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV63626141; called by muse, mutect2, varscan2
- ATR | c.7292G>A p.R2431K | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV63385598; called by muse, mutect2, varscan2
- ATR | c.2696A>C p.K899T | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as COSV63385601; called by muse, mutect2, varscan2
- ATRN | c.1114T>C p.Y372H | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV53526511; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AXIN2 | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100197113; called by muse, mutect2
- BABAM2 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV59620806; called by muse, mutect2, varscan2
- BAHD1 | c.886T>C p.S296P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69083822; called by muse, mutect2, varscan2
- BBOF1 | c.1582A>G p.T528A | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.164); catalogued as COSV63246194; called by muse, mutect2, varscan2
- BCAS1 | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65085195; called by muse, varscan2
- BCL9L | c.2315T>C p.M772T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV52683516; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as rs768244116; called by pindel, varscan2
- BICD2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.123); catalogued as COSV63548657; called by muse, mutect2, varscan2
- BICD2 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.883); catalogued as COSV63548666; called by muse, mutect2, varscan2
- BORA | c.758A>G p.E253G (on ENST00000613797; = p.E178G on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV64695118; called by muse, mutect2, varscan2
- BORCS6 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV66505025; called by muse, mutect2, varscan2
- BRINP2 | c.1756A>G p.M586V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV64176890; called by muse, mutect2, varscan2
- BRSK1 | c.481A>G p.N161D | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58665805; called by muse, mutect2, varscan2
- BRWD1 | c.3469T>A p.W1157R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60894611; called by muse, mutect2, varscan2
- BTAF1 | c.3926A>G p.H1309R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56432291; called by muse, mutect2, varscan2
- BTBD6 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV59267923; called by muse, mutect2, varscan2
- C12orf65 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV53516095; called by muse, mutect2, varscan2
- C14orf28 | c.244_245del p.L82Sfs*4 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs746382141; called by pindel, varscan2
- C18orf25 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99960293; called by muse, mutect2
- C2orf42 | c.1382T>A p.I461N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV52449751; called by muse, mutect2, varscan2
- C3orf20 | c.1663T>C p.F555L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV53784339; called by muse, mutect2, varscan2
- C6 | c.959T>C p.M320T | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV54708653; called by muse, mutect2, varscan2
- C9orf72 | c.591A>C p.E197D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as COSV66154672; called by muse, mutect2, varscan2
- CABIN1 | c.655T>C p.C219R | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV54080500; called by muse, mutect2, varscan2
- CACNA1D | c.2789T>C p.F930S (on ENST00000350061 / NM_001128840.3; = p.F950S on NM_000720.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55443793; called by muse, mutect2, varscan2
- CAMK2D | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.207); catalogued as COSV56428886; called by muse, mutect2, varscan2
- CAPN7 | c.2205-2A>G p.X735_splice | Splice Site (SNP) | VAF 81/241 reads (34%) | catalogued as COSV53743728; called by muse, mutect2, varscan2
- CARD11 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV62717149; called by muse, mutect2, varscan2
- CARS1 | c.1275A>G p.S425= | Splice Region (SNP) | VAF 38/76 reads (50%) | catalogued as COSV53453060; called by muse, mutect2, varscan2
- CASP8AP2 | c.3755G>A p.R1252H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs374748337; called by muse, mutect2, varscan2
- CATSPER3 | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.344); catalogued as COSV50945869; called by muse, mutect2, varscan2
- CATSPERB | c.761del p.L254* | Frame Shift Del (DEL) | VAF 55/185 reads (30%) | catalogued as rs781475273; called by mutect2, pindel, varscan2
- CAV3 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.516); catalogued as rs1553613127, COSV100664436; ClinVar: uncertain significance; called by muse, mutect2
- CBY1 | c.175T>C p.W59R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53264160; called by muse, mutect2, varscan2
- CC2D2A | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.798); catalogued as rs867163730, COSV67503151; called by muse, mutect2, varscan2
- CC2D2B | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 71/186 reads (38%) | catalogued as COSV60357650; called by muse, mutect2, varscan2
- CCDC107 | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV58396879; called by muse, mutect2, varscan2
- CCDC110 | c.2275A>T p.T759S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV56870361; called by muse, mutect2, varscan2
- CCDC130 | c.754A>G p.S252G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV50004126; called by muse, mutect2, varscan2
- CCDC142 | c.1099T>C p.W367R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51777122; called by muse, mutect2, varscan2
- CCDC174 | c.908del p.K303Rfs*2 | Frame Shift Del (DEL) | VAF 103/348 reads (30%) | catalogued as rs1229700711; called by mutect2, pindel, varscan2
- CCDC18 | c.2928A>T p.L976F (on ENST00000343253 / NM_001306076.1; = p.L977F on NM_206886.4) | Missense Mutation (SNP) | VAF 115/317 reads (36%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.643); catalogued as COSV58142585; called by muse, mutect2, varscan2
- CCDC39 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368870111; ClinVar: uncertain significance; called by muse, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 38/74 reads (51%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC80 | c.1185G>C p.R395S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV99245467; called by mutect2, varscan2
- CCDC87 | c.1268C>A p.P423Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV59578766; called by muse, mutect2, varscan2
- CCN2 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV63466613; called by muse, mutect2, varscan2
- CCNB1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 23/58 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56509767; called by muse, mutect2, varscan2
- CCNJL | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57444283; called by muse, mutect2, varscan2
- CCNK | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs532436153, COSV66274574; called by muse, mutect2, varscan2
- CCR7 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs750217276, COSV55849135; called by muse, mutect2, varscan2
- CCZ1B | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV57436875; called by muse, mutect2, varscan2
- CD209 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV52652011; called by muse, mutect2, varscan2
- CDC42SE1 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.376); catalogued as rs1428839169, COSV61785355; called by muse, mutect2, varscan2
- CDC6 | c.1475T>C p.V492A | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1208012507, COSV52930230; called by muse, mutect2, varscan2
- CDH12 | c.1396A>G p.N466D | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as COSV66398212; called by muse, mutect2, varscan2
- CDHR2 | c.2883T>G p.N961K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); catalogued as COSV56137154; called by muse, mutect2, varscan2
- CDK18 | c.1292T>C p.L431P (on ENST00000506784 / NM_212503.3; = p.L401P on NM_002596.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63727148; called by muse, mutect2, varscan2
- CDK2AP1 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV55542376; called by muse, mutect2
- CDX4 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV65171571; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 52/123 reads (42%) | catalogued as rs375852685; called by mutect2, varscan2
- CEMIP2 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs751260196, COSV65486661; called by muse, mutect2, varscan2
- CENPF | c.5951T>C p.M1984T | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs61741924, COSV100872105; called by muse, mutect2
- CENPQ | c.125del p.N42Ifs*5 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | catalogued as rs756590976; called by mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 33/252 reads (13%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP55 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV65184895; called by muse, mutect2, varscan2
- CERKL | c.1652G>A p.S551N (on ENST00000339098 / NM_001030311.2; = p.S525N on NM_201548.5) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1450685972, COSV100184317; called by muse, mutect2
- CFAP45 | c.812A>C p.E271A | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs961340993, COSV100928706; called by muse, mutect2
- CFAP54 | c.6880T>C p.C2294R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV61570661; called by muse, mutect2, varscan2
- CFAP70 | c.3280A>G p.I1094V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60282478; called by muse, mutect2, varscan2
- CFAP91 | c.1409A>G p.N470S | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.058); catalogued as COSV56340342; called by muse, mutect2, varscan2
- CGN | c.3314T>C p.L1105P | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54969312; called by muse, mutect2, varscan2
- CHD5 | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); catalogued as COSV52412303; called by muse, mutect2, varscan2
- CHEK2 | c.1671+1G>T p.X557_splice (on ENST00000382580 / NM_001005735.2; = p.X514_splice on NM_007194.4) | Splice Site (SNP) | VAF 44/107 reads (41%) | catalogued as COSV60418825; called by muse, mutect2, varscan2
- CHERP | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV52223759; called by muse, mutect2, varscan2
- CHIC2 | c.387+2T>C p.X129_splice | Splice Site (SNP) | VAF 56/150 reads (37%) | catalogued as COSV55754901; called by muse, mutect2, varscan2
- CHL1 | c.934G>A p.A312T (on ENST00000397491 / NM_001253387.1; = p.A328T on NM_006614.4) | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56590865, COSV99851534; called by muse, mutect2, varscan2
- CHST14 | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60378606; called by muse, mutect2, varscan2
- CIZ1 | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.376); catalogued as COSV52970977; called by muse, mutect2, varscan2
- CLASRP | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99674246; called by muse, mutect2
- CLCN4 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 61/364 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.42); catalogued as COSV66466110; called by muse, mutect2, varscan2
- CLCN5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV56584309; called by muse, mutect2
- CLIC1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65383844; called by muse, mutect2, varscan2
- CLTCL1 | c.2366T>C p.L789P | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54228444; called by muse, mutect2, varscan2
- CMIP | c.1889A>G p.K630R (on ENST00000537098 / NM_198390.2; = p.K536R on NM_030629.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV67697897; called by muse, mutect2, varscan2
- CMYA5 | c.10253A>G p.Q3418R | Missense Mutation (SNP) | VAF 151/443 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1375596999, COSV71405261; called by muse, mutect2, varscan2
- CNBD2 | c.1502T>C p.L501P (on ENST00000373973 / NM_001365709.1; = p.L497P on NM_080834.4) | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62586752; called by muse, mutect2, varscan2
- CNNM1 | c.1994A>G p.N665S | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs751993329, COSV100764024; called by muse, varscan2
- CNNM1 | c.2494A>G p.T832A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100764025; called by muse, mutect2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP5 | c.3757T>C p.C1253R | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV70482034, COSV70517825; called by muse, mutect2, varscan2
- COL13A1 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62568700; called by muse, mutect2, varscan2
- COL4A3 | c.2591A>G p.Q864R | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV67414831; called by muse, mutect2, varscan2
- COL5A1 | c.4892C>T p.T1631M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs764446683, COSV65667847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs2854389, COSV60393990; called by muse, mutect2
- COPG1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV59113564; called by muse, mutect2, varscan2
- COPS3 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV52004952; called by muse, mutect2, varscan2
- CPEB3 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs749351946, COSV56454317; called by muse, mutect2, varscan2
- CPLANE2 | c.758del p.P253Qfs*24 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs1220027350, COSV100983273; called by mutect2, pindel, varscan2
- CPNE8 | c.427T>C p.C143R | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV58841488; called by muse, mutect2, varscan2
- CRBN | c.1178T>C p.I393T | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51640442; called by muse, mutect2, varscan2
- CREBBP | c.4483A>T p.K1495* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV52120080; called by muse, varscan2
- CREBL2 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1228359475, COSV57428010; called by muse, mutect2, varscan2
- CRLF3 | c.865C>G p.R289G | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV60835609; called by muse, mutect2, varscan2
- CRY1 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1412613683, COSV50481784; called by muse, varscan2
- CRYBA2 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55386426; called by muse, mutect2, varscan2
- CSDE1 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV54743889; called by muse, mutect2, varscan2
- CSMD1 | c.3253A>G p.T1085A (on ENST00000520002; = p.T1084A on NM_033225.6) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100155365; called by muse, mutect2
- CSMD2 | c.5980T>C p.C1994R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV53901605; called by muse, mutect2, varscan2
- CTNNB1 | c.2063T>C p.M688T | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV62697043; called by muse, mutect2, varscan2
- CTR9 | c.1717A>C p.N573H | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV63728351; called by muse, mutect2, varscan2
- CTSH | c.559A>G p.S187G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54984640; called by muse, mutect2, varscan2
- CTTNBP2NL | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 113/382 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV54744059; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 51/464 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); catalogued as COSV54744071, COSV54746804; called by muse, mutect2, varscan2
- CUBN | c.5431T>C p.Y1811H | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1396472867, COSV64713302; called by muse, mutect2, varscan2
- CUL2 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV66078252; called by muse, mutect2
- CXorf58 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV64858077; called by muse, mutect2, varscan2
- CYP11B2 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV59995508; called by muse, mutect2, varscan2
- CYTH4 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50631872; called by muse, mutect2, varscan2
- DCAF10 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs772316292, COSV54287804; called by muse, mutect2, varscan2
- DCT | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65468525; called by muse, mutect2, varscan2
- DCTN1 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs967117932, COSV62620221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDHD2 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV68157644; called by muse, mutect2, varscan2
- DDIAS | c.2512A>G p.I838V | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200675617; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX49 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53230154; called by muse, mutect2
- DEPDC1B | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54009263; called by muse, mutect2, varscan2
- DEPDC7 | c.766G>A p.A256T (on ENST00000241051 / NM_001077242.2; = p.A247T on NM_139160.2) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV53806670; called by muse, mutect2, varscan2
- DES | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV64660199; called by muse, mutect2, varscan2
- DGAT2L6 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60717500; called by muse, mutect2, varscan2
- DGKA | c.1846A>G p.R616G | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV59385564; called by muse, varscan2
- DHFR | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV101459104; called by muse, mutect2
- DHX57 | c.495A>C p.E165D | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54884186; called by muse, mutect2, varscan2
- DHX8 | c.2210T>C p.I737T | Missense Mutation (SNP) | VAF 158/348 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52252360; called by muse, mutect2, varscan2
- DICER1 | c.1936T>C p.F646L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58618139; called by muse, mutect2, varscan2
- DIDO1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56619118; called by muse, mutect2, varscan2
- DIP2B | c.3014A>G p.H1005R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56581997; called by muse, mutect2, varscan2
- DIP2C | c.2504T>C p.L835P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55153832; called by muse, mutect2, varscan2
- DIPK2B | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1219553300, COSV67641044; called by muse, mutect2, varscan2
- DIS3L | c.1691A>G p.E564G (on ENST00000319212 / NM_001143688.3; = p.E481G on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV59911858; called by muse, varscan2
- DLGAP2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV70096963; called by muse, mutect2, varscan2
- DMD | c.5033A>C p.Q1678P | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV63747702, COSV63804147; called by muse, mutect2, varscan2
- DNA2 | c.1856T>C p.V619A | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64428210; called by muse, mutect2, varscan2
- DNAH10 | c.10589T>C p.L3530P (on ENST00000409039; = p.L3469P on NM_207437.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68991579; called by muse, mutect2, varscan2
- DNAH5 | c.11147T>C p.F3716S | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54217889, COSV54235391; called by muse, mutect2, varscan2
- DNAH9 | c.10835T>C p.F3612S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99309007; called by muse, mutect2
- DNAJC10 | c.2375A>G p.E792G | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV51136918; called by muse, mutect2, varscan2
- DNHD1 | c.14012A>G p.Q4671R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs779375712, COSV54433622; called by muse, mutect2, varscan2
- DOC2A | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs746511437, COSV58751086; called by muse, mutect2, varscan2
- DOCK5 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV52399415; called by muse, mutect2, varscan2
- DOCK5 | c.1901A>G p.N634S | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52399429; called by muse, mutect2, varscan2
- DOCK8 | c.6146A>G p.N2049S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66619260; called by muse, mutect2, varscan2
- DOK3 | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV57251782; called by muse, mutect2, varscan2
- DPP9 | c.1322T>C p.F441S (on ENST00000598800; = p.F470S on NM_139159.5) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99506664; called by muse, mutect2
- DPP9 | c.211C>T p.R71C (on ENST00000598800; = p.R100C on NM_139159.5) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761219608, COSV53590565; called by muse, mutect2
- DRAM2 | c.517+2T>C p.X173_splice | Splice Site (SNP) | VAF 24/56 reads (43%) | catalogued as COSV54415113; called by muse, mutect2, varscan2
- DRD3 | c.613del p.V205Sfs*11 | Frame Shift Del (DEL) | VAF 56/206 reads (27%) | catalogued as COSV55679726, COSV55680316; called by mutect2, pindel, varscan2
- DROSHA | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 110/231 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV60774724; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 173/420 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DSP | c.4370T>A p.M1457K | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV104429123, COSV65792271; called by muse, mutect2, varscan2
- DSPP | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.169); catalogued as rs749568918, COSV56809601; called by muse, mutect2, varscan2
- DSTYK | c.2050G>T p.V684F | Missense Mutation (SNP) | VAF 117/348 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV65686135; called by muse, mutect2, varscan2
- DYNC1H1 | c.2123A>G p.Q708R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV64136075; called by muse, mutect2, varscan2
- DYSF | c.4403C>A p.P1468H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV50294179; called by muse, mutect2, varscan2
- DZANK1 | c.1954A>G p.K652E (on ENST00000262547 / NM_001099407.1; = p.K459E on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV52749949; called by muse, mutect2, varscan2
- E2F7 | c.177dup p.F60Ifs*12 | Frame Shift Ins (INS) | VAF 78/190 reads (41%) | catalogued as rs771114476; called by mutect2, varscan2
- E2F8 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100001840; called by muse, mutect2
- ECPAS | c.3162T>C p.G1054= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as COSV52195415; called by muse, mutect2, varscan2
- EFCAB5 | c.1818A>C p.Q606H | Missense Mutation (SNP) | VAF 150/485 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV57928288; called by muse, mutect2, varscan2
- EFTUD2 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs758438398, COSV68182787; called by muse, mutect2, varscan2
- EHHADH | c.1420G>T p.G474C | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51629231; called by muse, mutect2, varscan2
- EIF3I | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV59084310; called by muse, mutect2, varscan2
- EIF4E2 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 36/79 reads (46%) | catalogued as COSV51471599; called by muse, mutect2, varscan2
- ELL | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs753377816, COSV53212106; called by muse, mutect2, varscan2
- ELOA | c.1102A>C p.K368Q | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV69309924; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 72/208 reads (35%) | catalogued as rs766700925; called by mutect2, varscan2
- ELOA | c.1828T>C p.C610R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69309928; called by muse, mutect2, varscan2
- EMC2 | c.64T>C p.W22R | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55208749; called by muse, mutect2, varscan2
- EMILIN1 | c.2714-2A>G p.X905_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53154254; called by muse, mutect2, varscan2
- EML1 | c.2308T>A p.C770S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs758206081, COSV51743618; called by muse, mutect2, varscan2
- EML5 | c.5735T>C p.M1912T (on ENST00000380664; = p.M1920T on NM_183387.3) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV51768422; called by muse, mutect2, varscan2
- EP400 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368167632; called by muse, mutect2, varscan2
- EPB41L5 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs765044439, COSV55350984; called by muse, mutect2, varscan2
- EPHA1 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV51970393; called by muse, mutect2, varscan2
- EPHA6 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV67568249; called by muse, mutect2, varscan2
- EPRS1 | c.3425T>G p.I1142S | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100859556; called by muse, mutect2
- ERC1 | c.1769A>G p.K590R (on ENST00000360905 / NM_178040.4; = p.K562R on NM_178039.4) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV61693760; called by muse, mutect2, varscan2
- ERICH1 | c.373A>G p.N125D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV50637814; called by muse, mutect2, varscan2
- ERICH6 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753770853, COSV55798938; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs775950025; called by mutect2, varscan2
- ETS1 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60092936; called by muse, mutect2, varscan2
- EVPL | c.5972T>A p.L1991Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV56909687; called by muse, mutect2, varscan2
- EXOC3L1 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52045794; called by muse, mutect2, varscan2
- EXOC7 | c.570C>A p.H190Q | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58741031; called by muse, mutect2, varscan2
- EXPH5 | c.3202A>G p.N1068D | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV56200990; called by muse, mutect2, varscan2
- EYA2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57941387; called by muse, mutect2, varscan2
- EZH2 | c.1924T>C p.C642R (on ENST00000460911 / NM_001203247.2; = p.C647R on NM_004456.5) | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57445973; called by muse, mutect2
- F11 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV53001809; called by muse, mutect2, varscan2
- F2RL1 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 92/283 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV56995513; called by muse, mutect2, varscan2
- FABP2 | c.148_151del p.V50Kfs*23 | Frame Shift Del (DEL) | VAF 58/139 reads (42%) | catalogued as rs780659556; called by mutect2, pindel, varscan2
- FAM110B | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as COSV64064540; called by muse, mutect2, varscan2
- FAM222B | c.336A>G p.I112M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV57929654; called by muse, mutect2, varscan2
- FANCI | c.2954T>G p.L985R (on ENST00000310775 / NM_001376911.1; = p.L925R on NM_018193.3) | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55525659; called by muse, mutect2, varscan2
- FAT3 | c.3045A>T p.K1015N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV53098300; called by muse, mutect2, varscan2
- FAT3 | c.4657A>G p.I1553V | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.175); catalogued as COSV53098326; called by muse, mutect2, varscan2
- FAT4 | c.10246A>G p.S3416G | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs755037679, COSV58679667; called by muse, mutect2, varscan2
- FATE1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.299); catalogued as rs1318352178, COSV64848921; called by muse, mutect2, varscan2
- FBN3 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54458207; called by muse, mutect2
- FBXL7 | c.89del p.T30Sfs*17 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | catalogued as COSV61644450; called by mutect2, pindel, varscan2
- FBXO24 | c.322+2T>C p.X108_splice (on ENST00000241071 / NM_033506.3; = p.X146_splice on NM_012172.5) | Splice Site (SNP) | VAF 56/120 reads (47%) | catalogued as COSV53825196; called by muse, mutect2, varscan2
- FBXO30 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 156/376 reads (41%) | catalogued as COSV52790796; called by muse, mutect2, varscan2
- FBXO38 | c.3508G>A p.A1170T (on ENST00000340253 / NM_205836.3; = p.A1095T on NM_030793.5) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as COSV99694157; called by muse, mutect2
- FERMT1 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 124/365 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54092309; called by muse, mutect2, varscan2
- FGF1 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs773671222, COSV100532521; called by muse, mutect2
- FIBP | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV57033585; called by muse, mutect2, varscan2
- FLG | c.10144C>T p.R3382C | Missense Mutation (SNP) | VAF 230/665 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs147066553, COSV64245007; called by muse, mutect2, varscan2
- FLOT2 | c.1187A>C p.N396T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV67528971; called by muse, mutect2, varscan2
- FLT3 | c.1552A>G p.N518D | Missense Mutation (SNP) | VAF 102/201 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV54050287; called by muse, mutect2, varscan2
- FN1 | c.2890G>C p.V964L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.174); catalogued as COSV60550510; called by muse, mutect2, varscan2
- FNDC3B | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV61040420; called by muse, mutect2, varscan2
- FOXF2 | c.465C>A p.N155K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52525492; called by muse, mutect2, varscan2
- FPGS | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV64675502; called by muse, mutect2, varscan2
- FPR2 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs755457458, COSV60672507; called by muse, mutect2, varscan2
- FRA10AC1 | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 150/301 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63271517; called by muse, mutect2, varscan2
- FRG1 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as rs748595063, COSV56999259; called by muse, mutect2, varscan2
- FRMD7 | c.2095A>G p.T699A | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53745658; called by muse, mutect2, varscan2
- FRMPD1 | c.2066T>C p.L689P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV66700014; called by muse, mutect2, varscan2
- FRY | c.2145T>A p.N715K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV66568393; called by muse, mutect2, varscan2
- FTMT | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV58420182; called by muse, mutect2, varscan2
- FTSJ3 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as COSV59562027; called by muse, mutect2, varscan2
- FURIN | c.488T>A p.L163* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV51576020; called by muse, mutect2, varscan2
- FXN | c.277T>C p.W93R (on ENST00000377270; = p.W168R on NM_000144.5) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV101040192; called by muse, mutect2
- GAB2 | c.452A>G p.H151R (on ENST00000361507 / NM_080491.3; = p.H113R on NM_012296.3) | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60867118; called by muse, mutect2, varscan2
- GABRA5 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV59479824; called by muse, mutect2
- GALNT7 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1203966448, COSV53928729; called by muse, mutect2, varscan2
- GATM | c.365del p.K122Rfs*13 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | catalogued as rs1244883693; called by mutect2, pindel, varscan2
- GBF1 | c.3456A>T p.E1152D (on ENST00000369983 / NM_001377137.1; = p.E1151D on NM_004193.3) | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV64144215; called by muse, mutect2, varscan2
- GDPD2 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV65532639; called by muse, mutect2, varscan2
- GGA3 | c.2096C>T p.A699V (on ENST00000537686 / NM_138619.4; = p.A666V on NM_014001.5) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV55456179; called by muse, mutect2, varscan2
- GID4 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1225837408, COSV52008577; called by muse, mutect2, varscan2
- GLA | c.193A>G p.S65G | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs1569306013, COSV54508832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLDC | c.1555T>C p.F519L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV58678881; called by muse, mutect2, varscan2
- GLMP | c.701T>G p.F234C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828217; called by muse, mutect2
- GLS | c.1016T>G p.I339S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57841066; called by muse, mutect2, varscan2
- GM2A | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 78/158 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64095424; called by muse, mutect2, varscan2
- GMPPA | c.621-2A>G p.X207_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV58006583; called by muse, mutect2, varscan2
- GOLGA4 | c.3011T>C p.L1004P | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62710259; called by muse, mutect2, varscan2
- GOLGA4 | c.6446C>T p.A2149V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100729246; called by muse, mutect2
- GOLGA6A | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.153); catalogued as COSV99297445; called by mutect2, varscan2
- GOLGB1 | c.9287A>G p.Q3096R | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as COSV61464234; called by muse, mutect2, varscan2
- GPR39 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.131); catalogued as rs371700670; called by muse, mutect2, varscan2
- GPR65 | c.966A>G p.I322M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV50862505; called by muse, mutect2, varscan2
- GPRC5A | c.1069A>G p.S357G | Missense Mutation (SNP) | VAF 137/377 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV50007533; called by muse, mutect2, varscan2
- GPRIN1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs764198142, COSV56139472; called by muse, mutect2
- GREB1 | c.4387T>C p.Y1463H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.46); PolyPhen benign (0.072); catalogued as COSV52184687; called by muse, mutect2
- GRIP1 | c.2153A>G p.D718G (on ENST00000359742 / NM_001379345.1; = p.D666G on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54020755; called by muse, mutect2, varscan2
- GRIP2 | c.1129A>G p.K377E (on ENST00000619221; = p.K280E on NM_001080423.4) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV56120883; called by muse, mutect2, varscan2
- GRM3 | c.2255C>T p.T752I | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863036, COSV64479996; called by muse, mutect2
- GSTK1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1029453280, COSV64424186; called by muse, mutect2, varscan2
- GSTM2 | c.655T>C p.*219Qext*89 | Nonstop Mutation (SNP) | VAF 25/199 reads (13%) | catalogued as rs1194206497, COSV53982204; called by muse, mutect2, varscan2
- GTF2H2C | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV66287096; called by muse, mutect2, varscan2
- GTPBP3 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV50175302; called by muse, mutect2, varscan2
- H2BC18 | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV58944117; called by muse, mutect2, varscan2
- H2BC5 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as COSV56800620; called by muse, mutect2, varscan2
- H2BW1 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs377520401, COSV54219999; called by muse, mutect2, varscan2
- HABP2 | c.1195A>G p.S399G | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV63636396; called by muse, mutect2, varscan2
- HAS3 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54706568; called by muse, mutect2
- HAUS5 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs776000427, COSV52547470; called by muse, mutect2, varscan2
- HBP1 | c.729T>G p.C243W | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56017402; called by muse, mutect2, varscan2
- HCFC2 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57558401; called by muse, mutect2, varscan2
- HCFC2 | c.926dup p.N309Kfs*34 | Frame Shift Ins (INS) | VAF 70/158 reads (44%) | catalogued as rs776023139; called by mutect2, varscan2
- HCN1 | c.1459A>G p.M487V | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1407054365, COSV57504206; called by muse, mutect2, varscan2
- HCN3 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61360948; called by muse, mutect2, varscan2
- HCRTR2 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV63795124; called by muse, mutect2, varscan2
- HDAC6 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57806604; called by muse, mutect2, varscan2
- HDAC9 | c.2341G>T p.G781C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67771177; called by muse, mutect2, varscan2
- HEATR5B | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV99250497; called by muse, mutect2
- HECTD4 | c.11743G>A p.A3915T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs769609794, COSV66390098; called by muse, mutect2, varscan2
- HELB | c.2511A>G p.I837M | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV56073320; called by muse, mutect2, varscan2
- HEPHL1 | c.3188A>G p.Y1063C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59891108; called by muse, mutect2, varscan2
- HERC5 | c.1583A>C p.E528A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV52039015; called by muse, varscan2
- HGS | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61267460; called by muse, mutect2, varscan2
- HHIPL2 | c.395T>A p.L132H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564540; called by muse, mutect2, varscan2
- HIPK3 | c.3551A>G p.K1184R | Missense Mutation (SNP) | VAF 151/285 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs975026500, COSV57561942; called by muse, mutect2, varscan2
- HIVEP3 | c.4975A>G p.K1659E | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs1558078420, COSV56013505; called by muse, mutect2, varscan2
- HMGB2 | c.471+2T>C p.X157_splice | Splice Site (SNP) | VAF 45/143 reads (31%) | catalogued as COSV56633434; called by muse, mutect2, varscan2
- HMGCS1 | c.55A>T p.I19F | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs907841992, COSV57289881; called by muse, mutect2, varscan2
- HMOX2 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54859900; called by muse, mutect2
- HNRNPR | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as rs1159352584, COSV56420963; called by muse, mutect2, varscan2
- HOXC5 | c.619A>G p.R207G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375154084, COSV54536713; called by muse, mutect2, varscan2
- HSD17B11 | c.764A>G p.K255R | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV64154179; called by muse, mutect2, varscan2
- HSD17B4 | c.1512+2T>C p.X504_splice (on ENST00000414835 / NM_001199291.3; = p.X479_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 81/169 reads (48%) | catalogued as COSV56334898; called by muse, mutect2, varscan2
- HSD17B6 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs983637457, COSV59107576; called by muse, mutect2, varscan2
- HSF5 | c.552A>G p.G184= | Splice Region (SNP) | VAF 37/106 reads (35%) | catalogued as COSV60416200; called by muse, mutect2, varscan2
- HSPG2 | c.7616A>G p.E2539G | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65970684; called by muse, mutect2, varscan2
- IBTK | c.3338+2T>C p.X1113_splice | Splice Site (SNP) | VAF 33/91 reads (36%) | catalogued as rs766616279, COSV60392225; called by muse, mutect2, varscan2
- IFI27L2 | c.229A>T p.I77F | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53128157; called by muse, mutect2, varscan2
- IFT172 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 120/275 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV53132366; called by muse, mutect2, varscan2
- IGDCC3 | c.2332G>A p.G778S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs561788751, COSV60077221; called by muse, mutect2, varscan2
- IGKV2D-28 | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV71626352; called by mutect2, varscan2
- IGSF9B | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1343851795, COSV58064091; called by muse, mutect2, varscan2
- IL1R1 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs746483365, COSV99292975; called by muse, mutect2, varscan2
- IL27RA | c.1890del p.R631Gfs*37 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs748604064; called by mutect2, varscan2
- IL7R | c.713T>C p.M238T | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV57407561; called by muse, mutect2, varscan2
- IMPACT | c.850T>A p.C284S | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV52421709; called by muse, mutect2, varscan2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as COSV68960008; called by mutect2, varscan2
- INPP4B | c.692T>C p.L231S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV53720101; called by muse, mutect2, varscan2
- INSRR | c.3230A>G p.E1077G | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV63872270; called by muse, mutect2, varscan2
- IRS4 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV64533309; called by muse, mutect2, varscan2
- IRS4 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs1162876168, COSV64533314; called by muse, mutect2, varscan2
- ISX | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV58086237; called by muse, mutect2, varscan2
- ITPK1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs766724738, COSV50894734; called by muse, mutect2, varscan2
- ITPR3 | c.1247T>C p.M416T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as COSV65407973; called by muse, mutect2, varscan2
- ITSN1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV101180650, COSV66082550; called by muse, mutect2, varscan2
- JAK1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61089719; called by muse, mutect2, varscan2
- KALRN | c.1477T>C p.S493P | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV53760236; called by muse, mutect2, varscan2
- KANK1 | c.3537G>T p.K1179N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63211447; called by muse, mutect2, varscan2
- KANSL1L | c.1798A>T p.M600L | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as COSV55991321; called by muse, mutect2, varscan2
- KAT14 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV66607334; called by muse, mutect2, varscan2
- KAT2A | c.1993T>C p.S665P | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV52425331; called by muse, mutect2, varscan2
- KCNA5 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377168490, COSV52905005, COSV99363611; called by muse, mutect2, varscan2
- KCNC2 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54366892; called by muse, mutect2, varscan2
- KCND1 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as rs1041113966, COSV54413528; called by muse, mutect2, varscan2
- KCND2 | c.835A>G p.M279V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100479329; called by muse, mutect2
- KCNIP2 | c.229G>A p.V77M (on ENST00000356640 / NM_173191.3; = p.V92M on NM_014591.5) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV53306764; called by muse, mutect2, varscan2
- KCNK10 | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV56643037; called by muse, mutect2, varscan2
- KCTD19 | c.2301dup p.V768Rfs*12 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs759860142; called by mutect2, varscan2
- KCTD4 | c.745A>C p.I249L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.052); catalogued as COSV61239012; called by muse, mutect2, varscan2
- KDM1B | c.2338T>C p.Y780H (on ENST00000449850; = p.Y547H on NM_153042.4) | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV52809917; called by muse, mutect2, varscan2
- KDM2A | c.28T>C p.Y10H | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV67081730; called by muse, mutect2, varscan2
- KDM5A | c.1475T>G p.I492S | Missense Mutation (SNP) | VAF 111/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66991785; called by muse, mutect2, varscan2
- KIAA0100 | c.2639T>C p.V880A | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV66491948; called by muse, mutect2, varscan2
- KIAA0100 | c.2003T>A p.L668* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV66491958; called by muse, mutect2, varscan2
- KIAA0100 | c.1784T>C p.V595A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV66491968; called by muse, mutect2, varscan2
- KIAA1109 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774673562, COSV52668848; called by muse, mutect2, varscan2
- KIF1B | c.2018A>G p.D673G (on ENST00000377086 / NM_001365952.1; = p.D627G on NM_015074.3) | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55807186; called by muse, mutect2, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/110 reads (37%) | catalogued as rs1193021160; called by mutect2, pindel, varscan2
- KIF26B | c.2809G>A p.D937N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1279781334, COSV63639891; called by muse, mutect2
- KIF5A | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV54053592; called by muse, mutect2, varscan2
- KIR3DL2 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 87/454 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs937390156, COSV54391006; called by muse, varscan2
- KLC4 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52434896; called by muse, mutect2, varscan2
- KLHDC4 | c.1511A>C p.E504A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV54507323; called by muse, mutect2, varscan2
- KLHDC9 | c.667T>C p.W223R | Missense Mutation (SNP) | VAF 34/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100919711; called by muse, mutect2
- KLHL31 | c.517A>G p.M173V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1207509124, COSV100911738; called by muse, mutect2
- KLHL32 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV65111585, COSV65111969; called by muse, mutect2, varscan2
- KLHL34 | c.1024T>C p.Y342H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV65279111; called by muse, mutect2, varscan2
- KLHL7 | c.434A>G p.N145S (on ENST00000339077 / NM_001031710.3; = p.N97S on NM_018846.5) | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV59160903; called by muse, mutect2, varscan2
- KLRC3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); catalogued as COSV101122938; called by muse, mutect2
- KLRK1 | c.164dup p.C56Lfs*46 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | catalogued as rs756606329; called by mutect2, varscan2
- KMT2E | c.970A>C p.N324H | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57571928; called by muse, mutect2, varscan2
- KNL1 | c.452A>G p.E151G (on ENST00000346991 / NM_170589.5; = p.E125G on NM_144508.5) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61153476; called by muse, mutect2, varscan2
- KNTC1 | c.2829T>G p.D943E | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.476); catalogued as COSV61079679; called by muse, mutect2, varscan2
- KRT17 | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60860553; called by muse, mutect2, varscan2
- KRT9 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV55852401; called by muse, mutect2, varscan2
- KRTAP10-12 | c.356G>A p.C119Y | Missense Mutation (SNP) | VAF 166/367 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV59958069; called by muse, mutect2, varscan2
- KRTAP10-2 | c.559T>A p.C187S | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV59958064; called by muse, mutect2, varscan2
- KRTAP9-2 | c.8A>G p.H3R | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV66646585; called by muse, mutect2, varscan2
- L3MBTL3 | c.1942A>C p.M648L | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs146332514, COSV100696513; called by muse, mutect2, varscan2
- LAMB2 | c.4269T>A p.C1423* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100026635; called by muse, mutect2
- LAMB2 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV59732633; called by muse, mutect2, varscan2
- LAMC2 | c.2321A>G p.N774S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51454479; called by muse, mutect2, varscan2
- LAMC3 | c.1724T>C p.L575P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63090175; called by muse, mutect2, varscan2
- LAPTM4B | c.811T>C p.Y271H (on ENST00000445593; = p.Y180H on NM_018407.6) | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71453961; called by muse, mutect2, varscan2
- LARS1 | c.1834G>A p.G612R (on ENST00000394434 / NM_020117.11; = p.G585R on NM_016460.3) | Missense Mutation (SNP) | VAF 250/562 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs771642013, COSV50974247; called by muse, mutect2, varscan2
- LCE5A | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.804); catalogued as COSV100524353; called by muse, mutect2
- LCN2 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52980359; called by muse, mutect2, varscan2
- LDAH | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1187288247, COSV52968838; called by muse, mutect2, varscan2
- LHCGR | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV99684406; called by muse, mutect2
- LIG1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV54390858; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 34/266 reads (13%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434dup p.N145Kfs*34 | Frame Shift Ins (INS) | VAF 120/276 reads (43%) | catalogued as rs748712732; called by mutect2, varscan2
- LONRF1 | c.1859A>G p.Y620C | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68036422; called by muse, mutect2, varscan2
- LONRF1 | c.1566+2T>C p.X522_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV68036428; called by muse, mutect2
- LRCH1 | c.421A>G p.N141D | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV60846152; called by muse, mutect2, varscan2
- LRFN2 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57826078; called by muse, mutect2, varscan2
- LRFN2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs749352903, COSV57826084; called by muse, mutect2, varscan2
- LRGUK | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs962001273, COSV99603883; called by muse, mutect2
- LRP11 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53333626; called by muse, mutect2, varscan2
- LRP12 | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52627675; called by muse, mutect2, varscan2
- LRRC17 | c.830A>C p.Y277S | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV50864458; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 56/158 reads (35%) | catalogued as rs745668314; called by mutect2, varscan2
- LSG1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763071707, COSV54569510; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs754757253, COSV52588935; called by mutect2, varscan2
- LYST | c.11017A>G p.I3673V | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1477463059, COSV67705993; called by muse, mutect2, varscan2
- LYST | c.9947A>G p.Q3316R | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67705996; called by muse, mutect2, varscan2
- LZTFL1 | c.516A>T p.E172D | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV56111248; called by muse, mutect2, varscan2
- MAGEA8 | c.736A>G p.R246G | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99674885; called by muse, mutect2
- MAGEH1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.038); catalogued as rs372274274, COSV61678974; called by muse, mutect2, varscan2
- MAGT1 | c.844G>A p.G282R (on ENST00000618282 / NM_001367916.1; = p.G314R on NM_032121.5) | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63234221; called by muse, mutect2, varscan2
- MAK16 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62452388; called by muse, mutect2, varscan2
- MAP3K12 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV57232346; called by muse, mutect2, varscan2
- MARF1 | c.2913T>G p.Y971* | Nonsense Mutation (SNP) | VAF 38/302 reads (13%) | catalogued as COSV60022254; called by muse, mutect2, varscan2
- MBD6 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV63073960; called by muse, mutect2, varscan2
- MBTPS1 | c.1564A>T p.M522L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV58570285; called by muse, mutect2, varscan2
- MCMBP | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 172/394 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV63508970; called by muse, mutect2, varscan2
- MDC1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as COSV64524164; called by muse, mutect2, varscan2
- MDGA1 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV51794556; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | catalogued as rs35107588; called by mutect2, varscan2
- MEF2D | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV61727655; called by muse, mutect2, varscan2
- MEGF9 | c.1616G>C p.R539P | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64235154; called by muse, mutect2, varscan2
- MEIS2 | c.620C>T p.S207F (on ENST00000561208 / NM_170675.5; = p.S194F on NM_002399.3) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.713); catalogued as COSV54933929; called by muse, mutect2, varscan2
- MELTF | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as COSV56380596; called by muse, mutect2, varscan2
- METTL16 | c.757T>C p.C253R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV54013208; called by muse, mutect2, varscan2
- MIS18A | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV99267173; called by muse, mutect2
- MISP | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV53119569; called by muse, mutect2, varscan2
- MKI67 | c.1871T>C p.L624P | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV64073842; called by muse, mutect2, varscan2
- MLH1 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.05); catalogued as COSV51616750; called by muse, mutect2, varscan2
- MLXIP | c.2603T>C p.L868P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59834696; called by mutect2, varscan2
- MMP14 | c.364A>C p.N122H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV61288018; called by muse, mutect2, varscan2
- MMUT | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV51273158, COSV51274274; called by muse, mutect2, varscan2
- MOK | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51964534; called by muse, varscan2
- MON1B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); catalogued as rs1182511264, COSV50246143; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2962T>C p.S988P | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56618600; called by muse, mutect2, varscan2
- MPL | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752112087, COSV65244598; called by muse, mutect2, varscan2
- MPP2 | c.1387G>A p.A463T (on ENST00000461854 / NM_001278372.2; = p.A439T on NM_005374.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs374135897; called by muse, mutect2, varscan2
- MPP6 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 94/109 reads (86%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV56037295; called by muse, mutect2, varscan2
- MRC1 | c.2786T>C p.I929T | Missense Mutation (SNP) | VAF 207/457 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV99519563; called by muse, mutect2, varscan2
- MRPS9 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs765595224, COSV51518896; called by muse, mutect2, varscan2
- MS4A15 | c.355A>G p.I119V (on ENST00000405633 / NM_001098835.2; = p.I26V on NM_152717.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV61961101; called by muse, mutect2, varscan2
- MSL2 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1210917126, COSV53862356; called by muse, mutect2, varscan2
- MTHFSD | c.667A>G p.I223V (on ENST00000360900 / NM_001159377.2; = p.I222V on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV59802793; called by muse, mutect2, varscan2
- MTMR4 | c.60dup p.K21Qfs*20 | Frame Shift Ins (INS) | VAF 28/54 reads (52%) | catalogued as rs750261859; called by mutect2, varscan2
- MUC17 | c.7387G>T p.V2463F | Missense Mutation (SNP) | VAF 154/331 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV60285677; called by muse, mutect2, varscan2
- MUC7 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 157/448 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as COSV59217933; called by muse, mutect2, varscan2
- MUTYH | c.1460T>C p.M487T | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV58343960; called by muse, mutect2, varscan2
- MYBPC3 | c.3736T>G p.F1246V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57025922; called by muse, mutect2, varscan2
- MYH10 | c.4567G>A p.V1523M | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52598746; called by muse, mutect2, varscan2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 46/122 reads (38%) | catalogued as rs752868848; called by pindel, varscan2
- MYH4 | c.5280G>T p.K1760N | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55116231; called by muse, mutect2, varscan2
- MYL6B | c.56A>T p.K19I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52878565; called by muse, mutect2, varscan2
- MYLK3 | c.1778A>T p.D593V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV67363672; called by muse, mutect2, varscan2
- MYO3A | c.4514C>A p.P1505H | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV56326925; called by muse, mutect2, varscan2
- MYO7B | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs370073682; called by muse, mutect2, varscan2
- MYOC | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | catalogued as COSV50679209, COSV99231790; called by muse, mutect2
- N4BP2 | c.2941A>G p.N981D | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54700965; called by muse, mutect2, varscan2
- NAT1 | c.788T>G p.I263R | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56984915; called by muse, mutect2, varscan2
- NCAPD2 | c.1396A>G p.T466A | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1282208474, COSV59698796; called by muse, mutect2, varscan2
- NCAPD2 | c.1797A>C p.K599N | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59698801; called by muse, mutect2, varscan2
- NCEH1 | c.1178A>G p.D393G (on ENST00000538775; = p.D353G on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56433972; called by muse, mutect2, varscan2
- NCKAP1 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100720629; called by muse, mutect2
- NEB | c.4733A>G p.E1578G | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV51100230; called by muse, mutect2, varscan2
- NEB | c.1990T>C p.F664L | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.986); catalogued as COSV51100601; called by muse, mutect2, varscan2
- NECTIN4 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs1376483844, COSV63512433, COSV63513038; called by muse, mutect2, varscan2
- NELFA | c.1597A>T p.K533* (on ENST00000542778; = p.K522* on NM_005663.5) | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100374111; called by muse, mutect2
- NELFB | c.787T>C p.Y263H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1339560558, COSV58024668; called by muse, mutect2, varscan2
- NFIB | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs370563581; called by muse, mutect2, varscan2
- NFYC | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV58126746; called by muse, mutect2, varscan2
- NID2 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs773897209, COSV53494973; called by muse, mutect2, varscan2
- NIN | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV55386902; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 43/383 reads (11%) | catalogued as rs763440516; called by mutect2, varscan2
- NLGN1 | c.1960A>G p.K654E | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100850437; called by muse, mutect2
- NLGN4X | c.2201T>C p.M734T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.09); catalogued as COSV52005180, COSV99324660; called by muse, mutect2
- NLRC5 | c.3854A>G p.Q1285R | Missense Mutation (SNP) | VAF 71/596 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV52653348; called by muse, mutect2, varscan2
- NLRP13 | c.145del p.Q49Rfs*12 | Frame Shift Del (DEL) | VAF 39/109 reads (36%) | catalogued as rs1198298310; called by mutect2, varscan2
- NMRAL1 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV52059614; called by muse, mutect2, varscan2
- NPBWR1 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100488350; called by muse, mutect2
- NPNT | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV59753083; called by muse, mutect2, varscan2
- NPR3 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54086467; called by muse, mutect2, varscan2
- NR4A1 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV54481687; called by muse, mutect2, varscan2
- NRSN2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66526661; called by muse, mutect2, varscan2
- NTRK1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100693914; called by muse, mutect2
- NUDT13 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV61968544; called by muse, mutect2, varscan2
- NUP133 | c.2240A>G p.N747S | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54570178; called by muse, mutect2, varscan2
- NUP98 | c.3568A>G p.T1190A (on ENST00000359171 / NM_001365126.1; = p.T1173A on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV61431031; called by muse, mutect2, varscan2
- OAT | c.1018T>G p.L340V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as COSV64347593; called by muse, mutect2, varscan2
- OBI1 | c.1446T>G p.S482R | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99932698; called by muse, mutect2
- OBSCN | c.7184C>A p.P2395H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV52762807; called by muse, mutect2, varscan2
- OCA2 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV62343178; called by muse, mutect2, varscan2
- OGG1 | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV56538374; called by muse, mutect2, varscan2
- OLFML2A | c.1574T>C p.V525A | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56582876; called by muse, mutect2, varscan2
- OR10H3 | c.202T>G p.S68A | Missense Mutation (SNP) | VAF 282/880 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100008565; called by muse, mutect2, varscan2
- OR10K1 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 190/777 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56871514; called by muse, varscan2
- OR14K1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757827913, COSV51720973; called by muse, mutect2, varscan2
- OR2AE1 | c.541T>C p.F181L | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60390017; called by muse, mutect2, varscan2
- OR2T12 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58777121; called by muse, mutect2, varscan2
- OR51G2 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs200630145, COSV58992505; called by muse, mutect2, varscan2
- OR6C65 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV65568385; called by muse, mutect2, varscan2
- OR6N2 | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 219/858 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV59410991; called by muse, mutect2, varscan2
- OR6Q1 | c.952T>C p.*318Rext*? | Nonstop Mutation (SNP) | VAF 58/137 reads (42%) | catalogued as COSV56932848; called by muse, mutect2, varscan2
- OR7D4 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV58071487; called by muse, mutect2, varscan2
- OR8D1 | c.499T>C p.S167P | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV63442037; called by muse, mutect2, varscan2
- OSBPL10 | c.1057T>A p.S353T | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV67338249; called by muse, mutect2, varscan2
- OSBPL10 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.87); catalogued as COSV67338259; called by muse, mutect2, varscan2
- OSBPL6 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs778733714, COSV51915264; called by muse, mutect2, varscan2
- OXSR1 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 102/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61258223; called by muse, mutect2, varscan2
- PAM | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57212047; called by muse, mutect2, varscan2
- PARP1 | c.1916A>G p.Y639C | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV64690003; called by muse, mutect2, varscan2
- PARP4 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV101132163; called by muse, mutect2
- PAX6 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM991010, COSV99570898; called by muse, mutect2
- PBRM1 | c.2461A>G p.T821A | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV56270577; called by muse, mutect2, varscan2
- PBRM1 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV56270607; called by muse, mutect2, varscan2
- PCCB | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV52444551; called by muse, mutect2, varscan2
- PCDH18 | c.2294T>C p.I765T | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100787578; called by muse, mutect2
- PCDHA5 | c.1549T>C p.Y517H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as rs561079678, COSV65351221; called by muse, mutect2, varscan2
- PCDHB3 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV50569059; called by muse, mutect2, varscan2
- PCDHB6 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50689499; called by muse, mutect2, varscan2
- PCDHGB3 | c.1861C>A p.L621M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53928963; called by muse, mutect2, varscan2
- PCDHGB4 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53928980; called by muse, mutect2, varscan2
- PCDHGB6 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53928991; called by muse, mutect2, varscan2
- PCLO | c.14987T>C p.V4996A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV61627800; called by muse, mutect2, varscan2
- PCM1 | c.5953A>G p.M1985V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV59586173; called by muse, mutect2, varscan2
- PCNT | c.6335A>G p.D2112G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV64027090; called by muse, mutect2, varscan2
- PCSK5 | c.4454A>G p.Q1485R | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as rs779995980, COSV101377751; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 23/222 reads (10%) | catalogued as rs781474699; called by mutect2, varscan2
- PDIA4 | c.1615A>G p.I539V (on ENST00000286091 / NM_001371244.1; = p.I538V on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs151183604; called by muse, mutect2, varscan2
- PDSS1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs762651649, COSV66058610; called by muse, mutect2, varscan2
- PEAR1 | c.2865del p.R956Gfs*30 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs774951036; called by mutect2, pindel, varscan2
- PERP | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101408612; called by muse, mutect2
- PFAS | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV58979644; called by muse, mutect2, varscan2
- PFN2 | c.325+2T>C p.X109_splice | Splice Site (SNP) | VAF 63/200 reads (32%) | catalogued as COSV53523273; called by muse, mutect2, varscan2
- PGD | c.1321A>G p.S441G | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV54621058; called by muse, mutect2, varscan2
- PHF21A | c.1605+2T>C p.X535_splice (on ENST00000418153 / NM_001101802.3; = p.X489_splice on NM_016621.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV57652499; called by muse, mutect2, varscan2
- PHOX2B | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV99891800; called by muse, mutect2
- PHTF2 | c.400T>C p.S134P (on ENST00000248550 / NM_001366089.1; = p.S96P on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV50325487; called by muse, mutect2, varscan2
- PIGA | c.1322T>A p.F441Y | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV61237384; called by muse, mutect2, varscan2
- PIK3C3 | c.1847T>G p.L616R | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV56278024; called by muse, varscan2
- PIK3CA | c.2597T>G p.L866W | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV55873389; called by muse, mutect2, varscan2
- PIK3R6 | c.1328A>G p.Q443R | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769892050, COSV100267038; called by muse, mutect2, varscan2
- PKDCC | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749057996, COSV54306467; called by muse, mutect2
- PKHD1 | c.9146A>G p.H3049R | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.901); catalogued as rs367678592, CM100411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.7546T>C p.F2516L | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV61870117; called by muse, mutect2, varscan2
- PLCZ1 | c.569+2T>C p.X190_splice | Splice Site (SNP) | VAF 38/82 reads (46%) | catalogued as COSV99857198; called by muse, mutect2
- PLEKHA1 | c.704T>A p.I235K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64569238; called by muse, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 45/102 reads (44%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHG4B | c.2689T>G p.Y897D (on ENST00000283426; = p.Y1253D on NM_052909.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99361359; called by muse, mutect2
- PLG | c.1588T>C p.Y530H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1490110246, COSV51982108; called by muse, mutect2, varscan2
- PLIN4 | c.1645G>A p.G549S (on ENST00000301286; = p.G564S on NM_001367868.2) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV56690094; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1266dup p.H423Tfs*4 | Frame Shift Ins (INS) | VAF 71/263 reads (27%) | catalogued as rs780662433; called by mutect2, pindel, varscan2
- PNMA5 | c.1105G>A p.V369M | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs782127676, COSV62625499; called by muse, mutect2, varscan2
- PNN | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53766016; called by muse, mutect2, varscan2
- PNPLA4 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs186093844, COSV101124406, COSV66853909; called by muse, mutect2, varscan2
- POLE | c.5666A>G p.Y1889C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57678200; called by muse, mutect2, varscan2
- POLH | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV64779274; called by muse, mutect2, varscan2
- POLK | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54034166; called by muse, mutect2, varscan2
- POLN | c.2003A>G p.Q668R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV67024602; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs149830208; called by muse, mutect2, varscan2
- PPHLN1 | c.1001T>C p.L334S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56733701; called by muse, mutect2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 63/189 reads (33%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPP1R10 | c.853+2T>C p.X285_splice | Splice Site (SNP) | VAF 89/283 reads (31%) | catalogued as COSV64738926; called by muse, mutect2, varscan2
- PPP1R7 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144669419, COSV99298139; called by muse, mutect2, varscan2
- PPP4C | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1567336350, COSV54221585; called by muse, mutect2, varscan2
- PRAM1 | c.1974C>T p.C658= | Splice Region (SNP) | VAF 3/12 reads (25%) | catalogued as rs200993518; called by muse, mutect2
- PRAM1 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as rs1346695383, COSV55313145; called by muse, mutect2, varscan2
- PRAMEF5 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 43/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100871357; called by muse, mutect2, varscan2
- PRDM5 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 57/108 reads (53%) | catalogued as rs1490743354, COSV53358821, COSV53369111; called by muse, varscan2
- PREX1 | c.4691T>C p.L1564P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV64250555; called by muse, mutect2, varscan2
- PREX2 | c.4711G>T p.A1571S | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as COSV55763315; called by muse, mutect2, varscan2
- PRICKLE2 | c.2201A>T p.D734V (on ENST00000295902; = p.D678V on NM_198859.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV55765375, COSV55766753; called by muse, mutect2, varscan2
- PRIMPOL | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV59248397; called by muse, mutect2, varscan2
- PRKD2 | c.2119T>C p.F707L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV52185878; called by muse, mutect2, varscan2
- PRKDC | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV58049265; called by muse, mutect2, varscan2
- PROX2 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV101507834; called by muse, mutect2
- PRPF4B | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 97/182 reads (53%) | catalogued as COSV61783436; called by muse, mutect2, varscan2
- PRPF4B | c.2461A>G p.I821V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV100528461; called by muse, mutect2
- PRRC2B | c.2416A>G p.S806G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV61935948; called by muse, mutect2, varscan2
- PRRC2C | c.1661A>G p.Q554R (on ENST00000367742; = p.Q552R on NM_015172.4) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.079); catalogued as COSV58903851; called by muse, mutect2, varscan2
- PSD3 | c.3091T>A p.S1031T (on ENST00000440756; = p.S1030T on NM_015310.4) | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV54069852; called by muse, mutect2, varscan2
- PSMA7 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53379788; called by muse, mutect2, varscan2
- PSMB11 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as rs774869639, COSV57460101; called by muse, mutect2, varscan2
- PTGDR | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs758233951; called by muse, mutect2, varscan2
- PTGER4 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV56720623; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1331T>C p.V444A (on ENST00000421990 / NM_001136042.2; = p.V426A on NM_025267.3) | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as COSV64182435; called by muse, mutect2, varscan2
- PTPRF | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.175); catalogued as COSV63444253; called by muse, mutect2, varscan2
- PTPRN | c.356del p.P119Qfs*81 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs759562798; called by mutect2, pindel
- PTPRO | c.2741T>G p.L914R (on ENST00000281171 / NM_030667.3; = p.L886R on NM_002848.4) | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55507465; called by muse, mutect2, varscan2
- PTPRS | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV53616685; called by muse, mutect2, varscan2
- PTPRU | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60525710; called by muse, mutect2, varscan2
- PYGL | c.1062del p.F354Lfs*54 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | catalogued as COSV53585339; called by mutect2, pindel, varscan2
- QRICH1 | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1353136334, COSV62615113; called by muse, mutect2, varscan2
- QSOX2 | c.2000T>G p.L667R | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62393857; called by muse, mutect2, varscan2
- QTRT2 | c.1138A>G p.M380V | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55559746; called by muse, mutect2, varscan2
- R3HDM1 | c.581del p.P194Qfs*2 | Frame Shift Del (DEL) | VAF 55/190 reads (29%) | catalogued as rs1303724951; called by mutect2, pindel, varscan2
- RAB6D | c.622T>C p.C208R | Missense Mutation (SNP) | VAF 147/380 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs755965731, COSV72151645; called by muse, mutect2, varscan2
- RACGAP1 | c.1512A>G p.I504M | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56699020; called by muse, mutect2, varscan2
- RAD9B | c.1234+1G>A p.X412_splice | Splice Site (SNP) | VAF 9/265 reads (3%) | catalogued as rs1414478900, COSV100799481, COSV62827039; called by muse, mutect2
- RASA3 | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV61866093; called by muse, mutect2, varscan2
- RASGRP3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV67821488; called by muse, mutect2, varscan2
- RB1 | c.2263T>A p.F755I | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034905, CM1110939, COSV57300805; called by muse, varscan2
- RBBP6 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV60504432; called by muse, mutect2, varscan2
- RBFOX1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV60954793; called by muse, mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 61/103 reads (59%) | catalogued as COSV60328025; called by mutect2, pindel, varscan2
- RBM10 | c.1724A>T p.D575V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61308108, COSV61308636; called by muse, mutect2, varscan2
- RBM11 | c.812A>G p.K271R | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as rs762833076, COSV101271259; called by muse, mutect2, varscan2
- RBM5 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.171); catalogued as rs370608309, COSV61737199; called by muse, mutect2, varscan2
- RBM5 | c.1455A>G p.Q485= | Splice Region (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61737206; called by muse, mutect2, varscan2
- RBM6 | c.1508T>C p.V503A | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV56481814; called by muse, mutect2, varscan2
- RBM6 | c.2372T>G p.I791R | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV56481828; called by muse, varscan2
- RBMS3 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV56139979; called by muse, mutect2, varscan2
- RBMX | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV57808877; called by muse, mutect2, varscan2
- RCOR3 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200119098, COSV65365452; called by muse, mutect2, varscan2
- RCSD1 | c.108+1G>A p.X36_splice | Splice Site (SNP) | VAF 38/120 reads (32%) | catalogued as rs1558088762, COSV63258591; called by muse, mutect2, varscan2
- RFC1 | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 234/520 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62899193; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs753959887; called by mutect2, varscan2
- RHCG | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51515398; called by muse, mutect2, varscan2
- RHOBTB2 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52570482; called by muse, mutect2, varscan2
- RHOJ | c.571A>C p.I191L | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV57457758; called by muse, mutect2, varscan2
- RIBC1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV51447841; called by muse, mutect2, varscan2
- RIBC2 | c.523T>C p.W175R | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.041); catalogued as COSV61581419; called by muse, mutect2, varscan2
- RIPK4 | c.1393G>A p.G465R (on ENST00000352483; = p.G417R on NM_020639.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs749690594, COSV60186715; called by muse, mutect2, varscan2
- RMC1 | c.1494+2T>C p.X498_splice | Splice Site (SNP) | VAF 45/133 reads (34%) | catalogued as COSV52571438; called by muse, mutect2, varscan2
- RNASE10 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60517606; called by muse, mutect2, varscan2
- RNF123 | c.1652del p.P551Lfs*11 | Frame Shift Del (DEL) | VAF 78/184 reads (42%) | catalogued as rs747041125; called by mutect2, pindel, varscan2
- ROPN1L | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56873557; called by muse, mutect2, varscan2
- ROR2 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65218251; called by muse, mutect2, varscan2
- RORA | c.422A>G p.D141G (on ENST00000335670 / NM_134261.3; = p.D166G on NM_002943.3) | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55037767; called by muse, mutect2, varscan2
- ROS1 | c.1087dup p.Y363Lfs*25 | Frame Shift Ins (INS) | VAF 8/103 reads (8%) | catalogued as rs1392239785; called by mutect2, pindel
- RP2 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs781792974, COSV54461481; called by muse, mutect2, varscan2
- RPE | c.215T>C p.M72T (on ENST00000359429 / NM_001318926.1; = p.M4T on NM_006916.2) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627218; called by muse, mutect2
- RPL17 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV59087551; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 38/64 reads (59%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.2879A>T p.K960M | Missense Mutation (SNP) | VAF 197/754 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV64819467; called by muse, mutect2, varscan2
- RPS6KA2 | c.802A>G p.M268V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1353018457, COSV55819138; called by muse, mutect2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | catalogued as rs756096568; called by mutect2, pindel, varscan2
- RRP12 | c.3128A>G p.K1043R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs1252515337, COSV59666850; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 124/164 reads (76%) | catalogued as rs759252078; called by mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | catalogued as rs759904440; called by mutect2, varscan2
- RUNX1 | c.398A>G p.D133G (on ENST00000344691 / NM_001001890.3; = p.D160G on NM_001754.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55873524, COSV55880140; called by muse, mutect2, varscan2
- RYR3 | c.9308T>C p.I3103T (on ENST00000389232; = p.I3104T on NM_001036.6) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV101215266; called by muse, mutect2, varscan2
- SAFB2 | c.634+2T>C p.X212_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | catalogued as COSV53041934; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as rs753320334; called by mutect2, pindel
- SAXO2 | c.551A>G p.H184R | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59753814; called by muse, mutect2, varscan2
- SBF1 | c.2930T>A p.L977Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV62367091; called by muse, mutect2, varscan2
- SBK1 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59396773; called by muse, mutect2, varscan2
- SBNO1 | c.2702A>G p.D901G (on ENST00000420886; = p.D900G on NM_018183.5) | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs774812067, COSV57340660; called by muse, mutect2, varscan2
- SCN11A | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 155/373 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367743263, COSV56572824; called by muse, mutect2, varscan2
- SCN5A | c.5971C>T p.R1991W (on ENST00000333535 / NM_198056.3; = p.R1990W on NM_000335.5) | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs371308670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.4774G>T p.G1592C (on ENST00000303354; = p.G1581C on NM_002977.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57606448; called by muse, mutect2, varscan2
- SCNN1A | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.467); catalogued as rs775062010, COSV57435025; called by muse, mutect2, varscan2
- SEC23IP | c.2449T>C p.F817L | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1365772848, COSV64831233; called by muse, mutect2, varscan2
- SEC24A | c.565+2T>C p.X189_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV59746296; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 44/73 reads (60%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEL1L | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568479591, COSV60919537, COSV60920043; called by muse, mutect2, varscan2
- SEMA4A | c.1300A>G p.M434V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs781112279, COSV61772485; called by muse, mutect2, varscan2
- SENP1 | c.1227dup p.G410Rfs*3 | Frame Shift Ins (INS) | VAF 30/56 reads (54%) | catalogued as rs750651342, COSV50304253; called by mutect2, varscan2
- SENP7 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs747057180, COSV58607892; called by muse, mutect2, varscan2
- SEPHS1 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV59257900; called by muse, mutect2, varscan2
- SERPINA4 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.162); catalogued as COSV54069602; called by muse, mutect2, varscan2
- SERTAD4 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs776195884, COSV100882687; called by muse, mutect2
- SETDB1 | c.2604A>T p.E868D | Missense Mutation (SNP) | VAF 116/403 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV54980727; called by muse, varscan2
- SGSM1 | c.3262T>C p.Y1088H (on ENST00000400359 / NM_001039948.4; = p.Y1027H on NM_133454.3) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV68509823; called by muse, mutect2, varscan2
- SHANK2 | c.2183C>A p.T728N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53594041; called by muse, mutect2, varscan2
- SHISAL2A | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 118/381 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.32); catalogued as COSV68979672; called by muse, mutect2, varscan2
- SI | c.5411A>G p.N1804S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV52273857; called by muse, mutect2, varscan2
- SIGLEC7 | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs370732295; called by muse, mutect2, varscan2
- SIGLEC8 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58473172; called by muse, mutect2, varscan2
- SIN3B | c.1266+2T>C p.X422_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56132438; called by muse, mutect2, varscan2
- SIPA1L3 | c.1393A>G p.S465G | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55912075; called by muse, mutect2, varscan2
- SIRPB1 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53538236; called by muse, mutect2, varscan2
- SIRPD | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.023); catalogued as COSV67546475; called by muse, mutect2, varscan2
- SIRT2 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV50874916; called by muse, mutect2, varscan2
- SLAMF8 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV99223152; called by muse, mutect2
- SLC11A2 | c.235T>A p.Y79N (on ENST00000394904 / NM_001379455.1; = p.Y50N on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50370229; called by muse, mutect2, varscan2
- SLC12A4 | c.1766A>G p.Y589C | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761042071, COSV50452575; called by muse, mutect2, varscan2
- SLC12A8 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58865192; called by muse, mutect2, varscan2
- SLC18B1 | c.1303A>G p.R435G | Missense Mutation (SNP) | VAF 124/292 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs181766051, COSV51594060; called by muse, mutect2, varscan2
- SLC1A3 | c.319+2T>C p.X107_splice | Splice Site (SNP) | VAF 152/440 reads (35%) | catalogued as COSV54315614; called by muse, varscan2
- SLC22A11 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57252681; called by muse, mutect2, varscan2
- SLC25A20 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59802638; called by muse, mutect2, varscan2
- SLC25A28 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV65125309; called by muse, mutect2, varscan2
- SLC26A5 | c.134A>C p.K45T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV59700392; called by muse, mutect2, varscan2
- SLC27A6 | c.1020A>G p.I340M | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV52482113; called by muse, mutect2, varscan2
- SLC28A1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54478121; called by muse, mutect2, varscan2
- SLC28A1 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV54478146; called by muse, mutect2, varscan2
- SLC28A1 | c.1793T>C p.V598A | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54478155; called by muse, mutect2, varscan2
- SLC29A3 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs200249218, COSV100928618; ClinVar: uncertain significance; called by mutect2, varscan2
- SLC35G1 | c.673A>G p.T225A (on ENST00000427197 / NM_001134658.3; = p.T224A on NM_153226.4) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV65055260; called by muse, mutect2, varscan2
- SLC4A2 | c.3338T>C p.I1113T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99880057; called by muse, mutect2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC4A4 | c.2018A>G p.E673G (on ENST00000264485 / NM_001098484.3; = p.E629G on NM_003759.4) | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV52621316; called by muse, mutect2, varscan2
- SLC52A3 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV54077150; called by muse, mutect2, varscan2
- SLC6A14 | c.1159+2T>C p.X387_splice | Splice Site (SNP) | VAF 119/235 reads (51%) | catalogued as COSV64146625; called by muse, mutect2, varscan2
- SLC6A6 | c.1120T>C p.Y374H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62648799; called by muse, mutect2, varscan2
- SLC7A3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs149506381, COSV53227102; called by muse, mutect2, varscan2
646 further variants in this file (319 protein-altering or splice-affecting, 296 silent, 31 other) are not listed here.
